Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4986, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4986-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

male with right renal mass.

TCGA - BP - 4986

Specimens Submitted:

1: SP: Kidney, right; partial nephrectomy

2: SP: Paracaval lymph nodes; regional resection

DIAGNOSIS:

1. SP: Kidney, right; partial nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 1.8 cm.

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

Not Identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not Identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

2. SP: Paracaval lymph nodes; regional resection (sr):

Lymph Nodes:

Not involved

Number of nodes examined:4

[page 2 of 2]
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1). The specimen is received fresh for frozen section and is labeled "right renal mass, stitch marks deep margin". It consists of a 4 x 3 x 2 cm wedge shaped portion of kidney with a suture marking the deep margin. The margin is inked black and the specimen is serially sectioned to reveal a well defined mass measuring 1.8 x 1.6 x 1.4 cm. It has yellow, white homogenous cut surface. The mass is 0.1 cm from the margin. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. Portions of the tumor are submitted for

Summary of sections:

FSC - frozen section control

T - tumor with margin

RS - representative sections, normal kidney parenchyma

2). The specimen is received in formalin, labeled "Paracaval lymph nodes" and consists of three pink tan firm lymph nodes ranging from 0.8 to 2.2 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes

BLN-- bisected lymph node

Summary of Sections:

Part 1: SP: Kidney, right; partial nephrectomy

Block	Sect. Site	PCs
1	fsc	1
1	rs	1
2	t	2

Part 2: SP: Paracaval lymph nodes; regional resection

Block	Sect. Site	PCs
1	BLN	2
1	LN	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL NEOPLASM; MARGINS ARE FREE OF TUMOR.
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file 5d667b3d-5f2c-4ea4-92c9-111eb7dbe323 (TCGA-BP-4986.04BA013D-E464-48BD-854C-095C79A30F7E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).